Somatic mutation profile of tumor specimen TARGET-10-PARNAF-03A (aliquot TARGET-10-PARNAF-03A-01D) from TARGET case TARGET-10-PARNAF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,678 days).
Specimen TARGET-10-PARNAF-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5f49c52-4148-4c25-9b33-c9a00c0e8652.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARNAF-10A (Blood Derived Normal), aliquot TARGET-10-PARNAF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f019f93-eeaf-4838-b70d-839de00c8b6f

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, Intron 3, Splice Site 2, Nonsense Mutation 2, Frame Shift Del 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD101 | c.1387A>G p.M463V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1034461311; called by muse, mutect2, varscan2
- TNFRSF25 | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.61); PolyPhen benign (0.167); catalogued as rs369260407, COSV99049115; called by muse, mutect2, varscan2
- ZC2HC1A | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as COSV55670698; called by muse, mutect2, varscan2
- ACBD3 | c.1399G>T p.A467S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.127); called by muse, mutect2
- ADAMTS18 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ASAP1 | c.1512_1514delinsAA p.L505Sfs*6 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | called by pindel, varscan2*
- BIRC6 | c.9166C>A p.P3056T | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- CCDC144A | c.3968C>T p.A1323V | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- COL6A2 | c.1255C>A p.P419T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CPXM1 | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- ENTPD1 | c.724T>A p.Y242N | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- N4BP2L2 | c.1374C>A p.N458K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIAS4 | c.902C>A p.A301E | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.046); called by muse, mutect2
- PNMA5 | c.242A>C p.H81P | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.306); called by mutect2, varscan2
- PPP2R5E | c.621_624delinsGG p.Y207* | Nonsense Mutation (DEL) | VAF 43/118 reads (36%) | called by pindel, varscan2*
- SLC2A7 | c.1192+1G>T p.X398_splice | Splice Site (SNP) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- SLC38A7 | c.612-1G>T p.X204_splice | Splice Site (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- THSD4 | c.2741C>A p.A914D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.386); called by muse, varscan2
- UEVLD | c.260G>T p.C87F | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- FLG | c.4710C>T p.S1570= | Silent (SNP) | VAF 15/160 reads (9%) | called by muse, mutect2
- SCN8A | c.3639C>A p.G1213= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV61983400; called by mutect2, varscan2
- XPO1 | c.333C>T p.I111= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV68947857; called by muse, mutect2
- AC092118.1 | n.882C>A | RNA (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- CCDC107 | chr9:35657931 C>T | 5'Flank (SNP) | VAF 15/66 reads (23%) | catalogued as rs1264110860; called by muse, mutect2, varscan2
- OBSCN | c.6755-187A>G | Intron (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2
- TTN | c.10361-4928del | Intron (DEL) | VAF 57/378 reads (15%) | catalogued as COSV59912417; called by mutect2, pindel, varscan2
- USP32P1 | n.334+944C>T | Intron (SNP) | VAF 24/196 reads (12%) | called by muse, varscan2
